CCDI case PBCAIM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/f8ab94a9-f42e-4bcb-8e5f-b4a6cc3a838f

Demographics
Sex at birth: female.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 5.0 years (1,832 days).

Biospecimens (2 samples)
- Sample 0DZ4M7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZ4NV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
